Somatic mutation profile of tumor specimen MP2PRT-PAPFFW-TMP1-A (aliquot MP2PRT-PAPFFW-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFFW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,148 days).
Specimen MP2PRT-PAPFFW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb202e49-6821-4e1d-b79e-86368c0dbbd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFFW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFFW-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/340fe224-0e5f-400a-8c82-e0a3df8fdbec

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR8K5 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1043395952, COSV100537208; called by muse, mutect2
- PKHD1L1 | c.7927C>G p.P2643A | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV65744402; called by muse, mutect2
- ZFHX4 | c.10454A>T p.E3485V | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1449035542; called by muse, mutect2, varscan2
- ADRB2 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CENPE | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP4 | c.2488T>C p.F830L | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DDX31 | c.1678G>C p.G560R | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAK1 | c.1093A>C p.N365H | Missense Mutation (SNP) | VAF 27/588 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.125); called by muse, mutect2
- STAT6 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 13/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2D3 | c.66_67insCC p.A23Pfs*31 | Frame Shift Ins (INS) | VAF 46/287 reads (16%) | called by mutect2, pindel, varscan2
